Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOJ, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AAOJ-01A (Primary Tumor).

[page 1 of 4]
Name:

Loc:

Acct#:

Ord #=

SURGICAL PATH

E SIGNED

Perform D/T=

(1 of 1)

***** ADDENDUM #1 *****

ADDENDUM REPORT:

FINAL DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. MIXED GERM CELL TUMOR, UNIFOCA (LARGEST FRAGMENT 9 CM), 50% YOLK SAC, 40 % IMMATURE AND MATURE TERATOMA, 10% SEMINOMA, left testis and spermatic cord, left radical orchiectomy (see note)
2. SPERMATIC CORD MARGIN FREE OF TUMOR
3. NO DIRECT EXTENSION OF INVASIVE TUMOR
4. LYMPHOVASCULAR INVASION NOT IDENTIFIED
5. NO RECOGNIZABLE TESTICULAR PARENCHYMA IDENTIFIED
6. pT1NxMx

Note: Because of the fragmentation of the specimen, evaluation of margins cannot be ascertained. The seminoma component is c-kit and PLAP positive and CAM 5.2 keratin stain negative. The yolk sac tumor is keratin and AFP strongly positive. CD30 is non-contributory. These findings support the above diagnosis.

Immunohistochemistry disclaimer:

This test was developed and its performance characteristics determined by It has not been
cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as

ICD.O-3

Mixed germ cell tumor 9085/3
Date @ Justice NDS 062.9
9/30/14

[page 2 of 4]
Name:

Loc:

DOB:

SURGICAL PATH

(Continued)

Acct#:

investigational or for research. This Laboratory is certified under the Clinical Laboratory Improvements of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Dictated By:

Released By: -----

SIGNED

Transcribed:

Specimen Source: L TESTIS SPERMATIC C

CASE NO.:

GROSS EXAM DATE:

PHYSICIAN & PAGER #:

PRELIMINARY DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. MIXED GERM CELL TUMOR, UNIFOCAL (LARGEST FRAGMENT 9 CM), 50% YOLK SAC, 40 % IMMATURE AND MATURE TERATOMA, 10% SEMINOMA, left testis and spermatic cord, left radical orchiectomy (see note)
2. SPERMATIC CORD MARGIN FREE OF TUMOR
3. NO DIRECT EXTENSION OF INVASIVE TUMOR
4. LYMPHOVASCULAR INVASION NOT IDENTIFIED
5. NO RECOGNIZABLE TESTICULAR PARENCHYMA IDENTIFIED
6. pT1NxMx

Note: Because of the fragmentation of the specimen, evaluation of margins cannot be ascertained. Special stains pending.

GROSS DESCRIPTION:

[page 3 of 4]
Name:

DOB:

Loc:

Att:

SURGICAL PATH

(Continued)

Acct#:

One specimen received, fixed in formalin, labeled with the patient's name, medical record number, and "left testis and spermatic cord." It consists of a fragmented specimen consisting of the spermatic cord, epididymis, fragments of testis parenchyma. Because this specimen is received fragmented, the exterior is not inked. The entire specimen weighs 150 gm. The spermatic cord is 8 cm in length x 1.3 cm in diameter. The epididymis is 3.5 x 2 x 0.5 cm. The main specimen measures 9 x 6.5 x 3 cm in aggregate and is white-pink soft tissue with focal areas of cystic spaces.

SUMMARY OF CASSETTES:

1. Spermatic cord margin.
- 2.7 Tumor.
8. Dense fibrous tissue.
9. epididymis
- 10-11 Additional sections of spermatic cord R11.

Dictated By:

*PW TSS dx discrepancy form
TCGA tumor is: yolk sac 50%
mature teratoma 50%*

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Yolk Sac 50%, Immature and Mature Teratoma 40%, Seminoma 10%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Yolk Sac Tumor 50%, Teratoma (Mature) 50%,	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file bcdb73d1-87a7-42f1-87fb-62475b1a3ac6 (TCGA-XE-AAOJ.2EF5F7E1-5863-4E99-B4EE-3152B19FFCE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).